Somatic mutation profile of tumor specimen MP2PRT-PATLEC-TBP1-A (aliquot MP2PRT-PATLEC-TBP1-A-1-0-D-A81Y-36) from MP2PRT case MP2PRT-PATLEC, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.6 years (1,300 days).
Specimen MP2PRT-PATLEC-TBP1-A: Sample type: Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Whole Blood; Biospecimen anatomic site: Blood; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a090cc7e-e671-4112-b868-311374d7bbb4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PATLEC-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PATLEC-NB1-A-1-0-D-A81Y-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1567801a-19e7-45e5-859b-f75551b12680

The open-access MAF lists 18 somatic variants for this specimen: 9 protein-altering or splice-affecting, 9 silent.
By variant classification: Silent 9, Missense Mutation 7, In Frame Ins 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- C10orf71 | c.130G>A p.E44K | Missense Mutation (SNP) | VAF 38/472 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs535438774; called by muse, mutect2
- CSHL1 | c.221C>A p.S74* | Nonsense Mutation (SNP) | VAF 53/295 reads (18%) | catalogued as COSV51989145; called by muse, mutect2, varscan2
- KCNG4 | c.793G>A p.V265M | Missense Mutation (SNP) | VAF 91/333 reads (27%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.523); catalogued as rs142370778; called by muse, mutect2, varscan2
- KRAS | c.350A>T p.K117I | Missense Mutation (SNP) | VAF 21/255 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.52); catalogued as COSV55937655; called by muse, mutect2
- LRRIQ1 | c.4329A>C p.E1443D | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV67836905; called by muse, mutect2, varscan2
- TBL1XR1 | c.1459T>A p.F487I | Missense Mutation (SNP) | VAF 47/330 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- TENT5D | c.92G>A p.G31E | Missense Mutation (SNP) | VAF 59/210 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- XKR6 | c.1214G>T p.G405V | Missense Mutation (SNP) | VAF 97/454 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- ZFHX3 | c.9295_9297dup p.G3099dup | In Frame Ins (INS) | VAF 86/308 reads (28%) | called by mutect2, pindel, varscan2
- CDCA2 | c.999A>G p.K333= | Silent (SNP) | VAF 21/278 reads (8%) | called by muse, mutect2
- DSCAML1 | c.2154C>T p.S718= (on ENST00000321322; = p.S658= on NM_020693.4) | Silent (SNP) | VAF 26/426 reads (6%) | catalogued as rs1156999877; called by muse, mutect2
- ENPP4 | c.654C>T p.V218= | Silent (SNP) | VAF 19/327 reads (6%) | called by muse, mutect2
- GFOD1 | c.492C>T p.C164= | Silent (SNP) | VAF 52/552 reads (9%) | catalogued as rs530842997, COSV64954298; called by muse, mutect2
- IGHV1-45 | c.353A>C p.*118= | Silent (SNP) | VAF 38/76 reads (50%) | called by muse, mutect2, varscan2
- KCND2 | c.480C>T p.S160= | Silent (SNP) | VAF 168/505 reads (33%) | catalogued as rs761095237, COSV58581400; called by muse, mutect2, varscan2
- LMO3 | c.36T>C p.G12= | Silent (SNP) | VAF 64/337 reads (19%) | called by muse, mutect2, varscan2
- SLC6A19 | c.453C>T p.S151= | Silent (SNP) | VAF 52/264 reads (20%) | catalogued as rs756989097; ClinVar: likely benign; called by muse, mutect2, varscan2
- ZBED1 | c.1899G>A p.R633= | Silent (SNP) | VAF 87/894 reads (10%) | called by muse, mutect2
